FM case AD13610 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/f1eadaa0-98f0-4fff-98bc-770c13ae0bf4

Female, 75.8 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the esophagus; primary biopsied or resected from the esophagus. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
